Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H3-01A from TCGA case TCGA-2Y-A9H3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 45.0 years (16,443 days).
Specimen TCGA-2Y-A9H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f496d40e-69f3-4350-8813-d3ed77339eeb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d5e312a-2896-4185-bd05-5c28cf29b95c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 20,578; copy number 2: 35,407; copy number 3: 2,658; copy number 4: 194; copy number 5: 39; copy number 6: 290; copy number 7: 461; copy number 8: 76; copy number 11: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H3-01A-11D-A381-01): tumor purity 0.35, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,623,382, 53 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1.
- chr8:6,044,353–6,885,276, 15 genes (within-gene range 0–1): AC009435.1, AC016065.1, MCPH1, AC016065.2, ANGPT2, AC018398.2, AF287957.1, MCPH1-AS1, MIR8055, AGPAT5, MIR4659A, MIR4659B, AF233439.2, XKR5, GS1-24F4.2.
- chr17:55,526,964–55,561,577, 3 genes (within-gene range 0–2): AC105021.1, GARS1P1, RNU6-1249P.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 904 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:1,341,044–14,400,963, 192 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr2:15,166,914–19,520,095, 55 genes, copy number 7–11: NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.3, AC079148.2, AC079148.1, RDH14, NT5C1B-RDH14, NT5C1B, RNU6-1215P, AC106053.1, AC130814.1, LINC01376, MIR4757, OSR1, AC010096.1, LINC01808.
- chr4:45,995,119–48,861,817, 37 genes, copy number 7: RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1.
- chr4:87,261,931–91,601,913, 69 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr7:9,614,978–9,851,386, 5 genes, copy number 7: GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1.
- chr7:40,135,005–40,860,763, 1 gene, copy number 7 (within-gene range 2–7): SUGCT.
- chr7:40,538,127–48,647,497, 137 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr7:57,060,590–62,275,678, 64 genes, copy number 7 (broad region; genes not listed).
- chr7:91,880,791–98,870,771, 130 genes, copy number 7 (broad region; genes not listed).
- chr7:98,881,650–98,881,729, 1 gene, copy number 7: MIR3609.
- chr7:113,415,689–118,513,830, 76 genes, copy number 8 (broad region; genes not listed).
- chr11:100,336,856–103,479,863, 61 genes, copy number 6 (broad region; genes not listed).
- chr15:101,168,530–101,933,350, 30 genes, copy number 6: AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr19:17,523,301–18,397,622, 46 genes, copy number 6: NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13, IL12RB1, MAST3, AC007192.2, AC007192.1, PIK3R2, IFI30, MPV17L2, RAB3A, AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189, LRRC25.

Autosomal genes at a single copy (total copy number 1): 18,158. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
